Surgical pathology report (de-identified scan), TCGA case TCGA-FF-A7CW, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site SingHealth, specimen TCGA-FF-A7CW-01A (Primary Tumor).

Patient Results

Requested By:

Histopathology Report

Biopsy No:

Final

Received Date/Time

Final

Reporting Information

Date/Time :

Final

Histopathologist :

Laboratory :

Consultant-In-Charge

Final

Submitting Physician

Final

Histopathology Report

Final

DIAGNOSIS

Cervical lymph node: Diffuse large B-cell lymphoma, non-germinal centre type (Hans' criteria).

GROSS DESCRIPTION

The specimen is received in formalin, labelled with patient's data and designated "cervical lymph node". It consists of several pieces of brownish tissue altogether measuring 2.5 x 2 x 0.6cm. (A1 & A2; no reserve)

MICROSCOPIC DESCRIPTION

Sections of lymph node show effacement of nodal architecture by a diffuse lymphomatous infiltrate featuring sheets of large cells with vesicular chromatin and prominent central nucleoli. There are frequent mitoses, apoptotic bodies and clusters of macrophages, thereby imparting a starry sky appearance. Immunohistochemistry confirms the B-cell lineage of the lymphomatous population, being positive for CD20. They lack expression of germinal centre markers CD10 and bcl6 (<30%) with strong expression of MUM1. There is no expression of CD30 and CD138 whilst in situ hybridization is negative for EBV-encoded RNA (EBER), thereby excluding plasmablastic lymphoma. CD21 fails to highlight any residual follicular dendritic meshwork and there is no overexpression of cyclin D1, which rules against pleomorphic variant mantle cell lymphoma. There is strong expression of bcl2 whilst the proliferation fraction is high at about 70% by Ki67 immunostaining.

Pathologist :

ICD-O-3

Lymphoma, diffuse large B-cell 9680/3

Site Cervical lymph node C77.0

JW 8/22/13

Reviewed (Initials):	8/14/13	

Printed from:

End of Report

Page: 1 of 1

Source: NCI Genomic Data Commons file b829480f-8704-4993-b996-9bfaa29610ca (TCGA-FF-A7CW.FF947398-211F-4ED6-A157-B86B7198B1B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).